Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BG, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BG-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Clinical Diagnosis & History:

Specimens Submitted:

- 1: Secondary nodule right medial thigh
- 2: Distal margin right thigh
- 3: Right thigh myxofibrosarcoma

DIAGNOSIS:

1. Soft tissue, right medial thigh, secondary nodule, excision:
- One benign lymph node.
2. Soft tissue, distal margin right thigh, excision:
- Benign skeletal muscle.
3. Soft tissue, right thigh, mass, radical resection:
- Myxofibrosarcoma, high grade, involving deep soft tissue of the thigh.
- Size: 17.2 cm in greatest dimension.
- Myxoid component: at least 50% of tumor.
- Necrosis is present (30% of tumor).
- Resection margins are uninvolved.

Note: The prior material [REDACTED] was reviewed.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

** Continued on next page **

ICD-O-3
Fibromyxosarcoma 8811/3
Site R Thigh NOS C49.2
01/22/13

[page 2 of 3]
----- Page 2 of 3

1) The specimen is received in formalin, labeled "Secondary nodule right medial thigh" and consists of unoriented, irregular fragment of fibroadipose tissue measuring 2.6 x 1.8 x 1.7 cm. The specimen is inked black and serially sectioned to reveal a tan-brown, ovoid, fleshy nodule measuring 0.9 x 0.8 x 0.6 cm that abuts the inked edge. The entire specimen is submitted. Photographs are taken.

Summary of sections:
FFT-full face of nodule submitted in one cassette
MM-perpendicular sections of nodule to closest margin
RS-remaining specimen

2) The specimen is received in formalin, labeled "Distal margin right thigh stitch marks true distal" and consists of a piece of red-brown, ragged skeletal muscle measuring 4.1 x 3.4 x 1.5 cm. A stitch at one edge of the specimen marks the true distal margin of excision, which is inked black. The tissue is serially sectioned and entirely submitted. Photographs are taken.

Summary of sections:
SS - sequential sections

3) The specimen is received fresh, labeled "Right thigh myxofibrosarcoma, black stitch -- proximal margin, white stitch -- lateral margin, skin superficial" and consists of an oriented, 26.9 x 16.9 x 1.2 cm soft tissue mass, with partially overlying, 26.9 x 3.1 x 0.1 cm smooth, focally scarred, tan-white skin ellipse. The specimen is oriented as follows: black stitch -- proximal margin, white stitch -- lateral margin, and skin superficial. The specimen is inked as follows: proximal yellow, distal -- orange, lateral -- green, medial blue, deep black, and superficial -- skin. The specimen is bivalved to reveal a 17.2 cm (proximal to distal) x 11.9 cm (medial to lateral) x 10.0 cm (anterior posterior), poorly defined, soft to rubbery, diffusely bulging, tan-yellow gelatinous mass with roughly 30% necrosis (proximal aspect). The mass is grossly adherent to the fascia of the surrounding muscle, and does not involve the overlying skin. The mass is located 0.2 cm from the closest deep margin, 0.9 cm from the proximal margin, 3.7 cm from the distal margin, 0.6 cm from the lateral margin, and 2.5 cm from the medial margin. A portion of tumor and normal tissue is submitted to TFS. The remaining specimen is representatively submitted for permanent. Photographs are taken.

Summary of sections:
M mass -- sequential sections of greatest dimension of mass, from proximal to distal
PRM -- proximal margin
DIM -- distal margin
MM medial margin
LM lateral margin
AM -- anterior margin -- skin scar
DM deep margin closest to mass

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

----- Page 3 of 3
MAM -- mass with surrounding muscle, representative

Summary of Sections:

Part 1: Secondary nodule right medial thigh

Block	Sect.	Site	PCs
1	FFT	1	
2	MM	5	
2	RS	2	

Part 2: Distal margin right thigh

Block	Sect.	Site	PCs
9	SS	9	

Part 3: Right thigh myxofibrosarcoma

Block	Sect.	Site	PCs
1	AM	2	
1	DIM	2	
1	DM	2	
1	LM	2	
10	M	10	
2	MAM	2	
1	MM	2	
1	PRM	2	

** End of Report **

Criteria:	kw 10/29/13	Yes	No
HIPAA Discrepancy	(NOT)		✓
Prior Malignancy History	breast	✓	NOT

Source: NCI Genomic Data Commons file dc86235e-be20-47f2-a718-142686c34504 (TCGA-DX-A8BG.EDCF1B7B-A06B-4C7B-B760-2DA993AD01EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).